CCDI case PBBUXK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/e6e54c3e-b28d-45b5-821e-dad67ce97466

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Intraductal papillary mucinous neoplasm with an associated invasive carcinoma: ICD-O-3 morphology code: 8453/3; Tissue or organ of origin: Ovary; Age at diagnosis: 15.7 years (5,745 days).

Biospecimens (3 samples)
- Sample 0DHY2Q: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHY40: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHY4P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
